Gene-level copy-number profile of tumor specimen TCGA-H5-A2HR-01A from TCGA case TCGA-H5-A2HR, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 71.1 years (25,986 days).
Specimen TCGA-H5-A2HR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.a6114b8c-e31d-451b-bb32-8fa69e06402d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-H5-A2HR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7c708a34-3427-40c4-bec0-c41d0461743e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 29; copy number 1: 23; copy number 2: 11,393; copy number 3: 3,647; copy number 4: 36,244; copy number 5: 932; copy number 6: 5,391; copy number 7: 368; copy number 8: 1,369; copy number 9: 284; copy number 10: 32; copy number 11: 70; copy number 12: 12; copy number 13: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-H5-A2HR-01A-11D-A17U-01): tumor purity 0.91, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:60,021,249–60,033,020, 1 gene: AC034234.1.
- chr14:50,397,013–50,561,126, 5 genes (within-gene range 0–2): AL359397.1, MAP4K5, AL118556.1, Y_RNA, AL118556.2.
- chr17:30,968,785–31,382,116, 13 genes (within-gene range 0–2): AC138207.9, RNF135, AC138207.4, DPRXP4, AC138207.7, AC138207.3, AC138207.8, AC138207.6, AC138207.2, MIR4733, NF1, AC079915.1, OMG.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 413 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:31,296,982–31,632,518, 12 genes, copy number 12 (within-gene range 6–12): ZCCHC17, AL451070.1, FABP3, SERINC2, AC209007.1, RNU6-40P, LDC1P, Y_RNA, LINC01226, AC114488.1, TINAGL1, HCRTR1.
- chr1:160,485,030–162,812,817, 98 genes, copy number 9–10 (broad region; genes not listed).
- chr1:162,824,795–162,849,467, 1 gene, copy number 10 (within-gene range 7–10): AL392003.2.
- chr3:125,225,669–125,756,462, 16 genes, copy number 9: ZNF148, DUTP1, DNAJB6P7, RNU6-232P, SNX4, Y_RNA, Y_RNA, OSBPL11, AF186996.3, AF186996.2, OR7E130P, OR7E29P, OR7E93P, OR7E53P, OR7E97P, AF186996.1.
- chr3:125,766,601–125,766,818, 1 gene, copy number 9: AC092902.5.
- chr8:127,735,434–128,564,679, 15 genes, copy number 13: MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824.
- chr10:122,416,965–123,058,290, 18 genes, copy number 9 (within-gene range 4–9): MIR3941, BX842242.1, ARMS2, HTRA1, DMBT1, AL603764.1, AL603764.2, C10orf120, DMBT1L1, CUZD1, AC073585.1, FAM24B, C10orf88B, FAM24A, C10orf88, PSTK, IKZF5, ACADSB.
- chr11:12,377,563–17,077,715, 69 genes, copy number 11 (broad region; genes not listed).
- chr11:17,115,652–17,115,763, 1 gene, copy number 11: RNU6-593P.
- chr11:24,496,970–31,369,810, 68 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr15:98,437,162–98,547,728, 1 gene, copy number 10 (within-gene range 6–10): FAM169B.
- chr17:79,915,252–80,542,605, 29 genes, copy number 9: LINC01979, LINC01978, TBC1D16, AC100791.3, AC116025.2, AC116025.1, CCDC40, MIR1268B, GAA, EIF4A3, AC087741.3, AC087741.2, CARD14, AC087741.1, SGSH, SLC26A11, RNF213, AC124319.1, AC124319.2, AC124319.3, RNF213-AS1, ENDOV, MIR4730, AC120024.1, AC120024.4, NPTX1, AC120024.2, AC120024.3, RPL32P31.
- chr17:80,602,549–80,602,926, 1 gene, copy number 9: RPL31P7.
- chr20:35,201,745–35,278,131, 1 gene, copy number 9 (within-gene range 5–9): MMP24OS.
- chr20:35,226,690–36,528,637, 47 genes, copy number 9 (within-gene range 4–9): MMP24, AL121753.2, AL121753.1, EIF6, FAM83C-AS1, FAM83C, UQCC1, GDF5-AS1, GDF5, MIR1289-1, CEP250, CEP250-AS1, FO393401.1, C20orf173, ERGIC3, RPL36P4, FER1L4, RPL37P1, SPAG4, CPNE1, AL109827.1, RN7SKP271, RNU6-759P, RBM12, NFS1, ROMO1, RBM39, RPF2P1, U6, PHF20, COX7BP2, Y_RNA, HIGD1AP16, RNU4-40P, RNU6-937P, SCAND1, CNBD2, NORAD, AL035420.1, AL035420.3, HMGB3P2, AL035420.2, EPB41L1, AL121895.1, AL121895.2, AAR2, DLGAP4.
- chr20:45,252,239–45,746,287, 34 genes, copy number 9: SLPI, MATN4, RBPJL, SDC4, AL021578.1, SYS1, SYS1-DBNDD2, TP53TG5, NDUFB4P10, DBNDD2, PIGT, MIR6812, AL031663.3, WFDC2, AL031663.2, RPL5P2, SPINT3, WFDC6, EPPIN-WFDC6, AL031663.1, HSPD1P21, EPPIN, WFDC8, RNA5SP485, CCNB1IP1P2, WFDC9, WFDC10A, RPS2P7, WFDC11, WFDC10B, WFDC13, MIR3617, SPINT4, HNRNPA1P3.
- chr20:45,749,920–45,750,074, 1 gene, copy number 9: SPINT5P.

Autosomal genes at a single copy (total copy number 1): 15. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
